TARGET case TARGET-15-SJMPAL043507 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/90b0734c-b375-42b7-a542-43e14d742fdb

Demographics
Sex at birth: male; Age at index: 7 years.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 7.4 years (2,707 days); Year of diagnosis: 2007.

Follow-up (1 entry)
- First event: Relapse; Timepoint: Follow-up.

Biospecimens (3 samples)
- Samples TARGET-15-SJMPAL043507-04A, TARGET-15-SJMPAL043507-04B (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL043507-15A: Sample type: Fibroblasts from Bone Marrow Normal; Tissue type: Normal; Specimen type: Fibroblasts from Bone Marrow.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Protocol: Singapore
- Karyotype: 47,XY,+8[20]
- WHO ALAL Classification: T/M
- WHO Dx: JMML
- WHO RL1: T/M
